Somatic mutation profile of cancer-model specimen HCM-CSHL-0241-C18-85A (3D Organoid; aliquot HCM-CSHL-0241-C18-85A-01D-A82H-36), derived from the primary tumor of HCMI case HCM-CSHL-0241-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-CSHL-0241-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 937374f7-8493-4b03-8ebd-f4af03d9dd5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0241-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0241-C18-11A-11D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9801f54c-9583-42ff-b034-894a607cd0ac

The open-access MAF lists 112 somatic variants for this specimen: 81 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 29, Nonsense Mutation 8, 5'UTR 1, Frame Shift Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 310/727 reads (43%) | catalogued as CM142940; called by muse, mutect2, varscan2
- AMPD3 | c.184G>A p.E62K (on ENST00000396553 / NM_001025389.2; = p.E71K on NM_000480.3) | Missense Mutation (SNP) | VAF 197/432 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV67329986; called by muse, mutect2, varscan2
- BCR | c.2321C>A p.P774H | Missense Mutation (SNP) | VAF 232/514 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV59935893; called by muse, mutect2, varscan2
- C3 | c.1934C>G p.T645S | Missense Mutation (SNP) | VAF 193/400 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs749155929; called by muse, mutect2, varscan2
- C4orf54 | c.4535G>A p.R1512H | Missense Mutation (SNP) | VAF 227/490 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as rs778635502; called by muse, varscan2
- CACNA1G | c.2454C>T p.S818= | Splice Region (SNP) | VAF 181/371 reads (49%) | catalogued as rs746536941; called by muse, mutect2, varscan2
- CASS4 | c.1687G>T p.V563F | Missense Mutation (SNP) | VAF 13/378 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64387689; called by muse, mutect2
- CAV3 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 147/342 reads (43%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.062); catalogued as rs867194464; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPS7A | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 229/525 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV99976413; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.2881C>T p.R961* | Nonsense Mutation (SNP) | VAF 24/637 reads (4%) | catalogued as rs1314983113; called by muse, mutect2
- CREB5 | c.1097G>A p.R366Q (on ENST00000357727 / NM_182898.4; = p.R359Q on NM_004904.3) | Missense Mutation (SNP) | VAF 254/539 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs376502932, COSV63228321; called by muse, mutect2, varscan2
- CSMD2 | c.9785C>T p.P3262L | Missense Mutation (SNP) | VAF 14/451 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1305136343; called by muse, mutect2
- FAT4 | c.6607C>T p.R2203W | Missense Mutation (SNP) | VAF 191/408 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs374328795, COSV58685192; called by muse, mutect2, varscan2
- FJX1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 417/944 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.235); catalogued as rs1302683529; called by muse, mutect2, varscan2
- GAL3ST4 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 287/599 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs544186969; called by muse, mutect2, varscan2
- HSPA12A | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 205/432 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs371819716; called by muse, mutect2, varscan2
- INSRR | c.3403G>A p.G1135R | Missense Mutation (SNP) | VAF 151/307 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780240706, COSV63875135; called by muse, mutect2, varscan2
- KCNQ2 | c.2332G>A p.E778K (on ENST00000359125 / NM_172107.4; = p.E750K on NM_004518.6) | Missense Mutation (SNP) | VAF 385/882 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.207); catalogued as rs1264858438, COSV100610604; called by muse, mutect2, varscan2
- KIR2DL3 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 101/219 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs771803423; called by muse, mutect2, varscan2
- LGI4 | c.61A>T p.R21* | Nonsense Mutation (SNP) | VAF 282/605 reads (47%) | catalogued as rs140614229; called by muse, varscan2
- MAP4K1 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 284/656 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369921707; called by muse, mutect2, varscan2
- MGRN1 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 189/449 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs896267391; called by muse, mutect2, varscan2
- MMP16 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 168/402 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54153184; called by muse, mutect2, varscan2
- MUC16 | c.29615C>A p.T9872K | Missense Mutation (SNP) | VAF 109/265 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.943); catalogued as rs762980584; called by muse, mutect2, varscan2
- NID1 | c.2117G>T p.R706L | Missense Mutation (SNP) | VAF 142/320 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as COSV51618836; called by muse, mutect2, varscan2
- NRXN1 | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 316/681 reads (46%) | catalogued as COSV68024296; called by muse, mutect2, varscan2
- OR13C3 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 205/437 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145157195, COSV66165876; called by muse, mutect2, varscan2
- OTOP2 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 280/575 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200725611, COSV58881356; called by muse, mutect2, varscan2
- PAK5 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 184/430 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760501160, COSV62030652, COSV62035511; called by muse, mutect2, varscan2
- PAMR1 | c.1711C>T p.R571C (on ENST00000619888 / NM_001001991.3; = p.R588C on NM_015430.4) | Missense Mutation (SNP) | VAF 236/485 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370534974, COSV99552139; called by muse, mutect2, varscan2
- PAX5 | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 255/537 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.124); catalogued as rs141574393; called by muse, mutect2, varscan2
- PCDH11X | c.3290G>A p.R1097H | Missense Mutation (SNP) | VAF 282/572 reads (49%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs769411878; called by muse, mutect2, varscan2
- POTEF | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 162/181 reads (90%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs750994299; called by muse, mutect2, varscan2
- PRTG | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 145/271 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs376631722, COSV101221365; called by muse, mutect2, varscan2
- RYR2 | c.3226G>A p.E1076K | Missense Mutation (SNP) | VAF 112/215 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs781547572, COSV63714171; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TIAM2 | c.3296G>A p.R1099H | Missense Mutation (SNP) | VAF 182/438 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs201811882, COSV51640227; called by muse, mutect2
- TMEM132A | c.1583C>T p.A528V (on ENST00000453848 / NM_178031.3; = p.A529V on NM_017870.4) | Missense Mutation (SNP) | VAF 356/788 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs1217494791; called by muse, mutect2
- TPBG | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 370/871 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV63882567; called by muse, mutect2, varscan2
- TRPC4 | c.2551C>T p.R851* (on ENST00000379705 / NM_016179.4; = p.R856* on NM_003306.3) | Nonsense Mutation (SNP) | VAF 151/316 reads (48%) | catalogued as rs773103339, COSV59011520; called by muse, mutect2, varscan2
- TRPS1 | c.2892C>A p.N964K (on ENST00000220888 / NM_001330599.2; = p.N977K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/562 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV55224422; called by muse, mutect2
- TTN | c.62132T>A p.L20711H (on ENST00000591111; = p.L13287H on NM_003319.4) | Missense Mutation (SNP) | VAF 54/125 reads (43%) | PolyPhen possibly damaging (0.479); catalogued as COSV60377573; called by muse, mutect2, varscan2
- ZBTB8B | c.1400C>T p.S467L | Missense Mutation (SNP) | VAF 218/474 reads (46%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.805); catalogued as rs916051056, COSV72152146; called by muse, mutect2, varscan2
- ZNF536 | c.3029C>T p.T1010M | Missense Mutation (SNP) | VAF 209/488 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100835152; called by muse, mutect2, varscan2
- ZNF735 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 191/425 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs558098312; called by muse, mutect2, varscan2
- ADCY9 | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 263/513 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- ADORA2B | c.833T>C p.L278P | Missense Mutation (SNP) | VAF 166/335 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKT3 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 169/364 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C18orf63 | c.76A>G p.I26V | Missense Mutation (SNP) | VAF 84/208 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL20A1 | c.2903G>A p.G968E | Missense Mutation (SNP) | VAF 133/317 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH17 | c.11874C>A p.S3958R | Missense Mutation (SNP) | VAF 234/486 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOT1L | c.3714C>A p.S1238R | Missense Mutation (SNP) | VAF 328/670 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM186A | c.5716C>T p.P1906S | Missense Mutation (SNP) | VAF 226/479 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- GATA1 | c.960T>G p.S320R | Missense Mutation (SNP) | VAF 392/875 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GOLGA6B | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 54/410 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRID2IP | c.1406G>C p.G469A | Missense Mutation (SNP) | VAF 190/371 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGHV3-53 | c.128C>G p.A43G | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- IGHV3-66 | c.128C>G p.A43G | Missense Mutation (SNP) | VAF 74/501 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- IQCC | c.391A>T p.K131* | Nonsense Mutation (SNP) | VAF 220/460 reads (48%) | called by muse, mutect2, varscan2
- KAT2B | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 95/287 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- MAP2 | c.2725G>T p.A909S | Missense Mutation (SNP) | VAF 153/370 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- MAPT | c.1509C>G p.S503R (on ENST00000262410 / NM_001377265.1; = p.S428R on NM_016835.4) | Missense Mutation (SNP) | VAF 361/749 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- MARCO | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2
- OR4S1 | c.292_293delinsT p.Q98Cfs*45 | Frame Shift Del (DEL) | VAF 206/763 reads (27%) | called by pindel, varscan2*
- PHLDB1 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 170/365 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PREX1 | c.1115G>T p.C372F | Missense Mutation (SNP) | VAF 16/577 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTPRQ | c.4531C>A p.L1511I (on ENST00000616559; = p.L1469I on NM_001145026.2) | Missense Mutation (SNP) | VAF 100/246 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- RAB31 | c.357C>G p.N119K | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RASAL2 | c.3030T>A p.Y1010* | Nonsense Mutation (SNP) | VAF 222/483 reads (46%) | called by muse, mutect2, varscan2
- RYR2 | c.5849C>G p.A1950G | Missense Mutation (SNP) | VAF 237/521 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SASH1 | c.3080C>A p.A1027D | Missense Mutation (SNP) | VAF 329/705 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPTY2D1 | c.1083T>G p.N361K | Missense Mutation (SNP) | VAF 248/480 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STK10 | c.266A>C p.D89A | Missense Mutation (SNP) | VAF 212/514 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- SYAP1 | c.975A>T p.Q325H | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYT16 | c.458G>C p.G153A | Missense Mutation (SNP) | VAF 156/354 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TLR1 | c.1033T>A p.S345T | Missense Mutation (SNP) | VAF 148/343 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRPM2 | c.339G>A p.W113* | Nonsense Mutation (SNP) | VAF 252/535 reads (47%) | called by muse, mutect2, varscan2
- TYR | c.968G>T p.S323I | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); called by muse, mutect2
- VPS50 | c.2858T>C p.L953P | Missense Mutation (SNP) | VAF 102/204 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WASHC4 | c.1514C>T p.T505I | Missense Mutation (SNP) | VAF 135/332 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX3 | c.2606A>G p.N869S | Missense Mutation (SNP) | VAF 224/527 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF670 | c.550T>G p.F184V | Missense Mutation (SNP) | VAF 107/235 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ALOXE3 | c.1623G>A p.S541= | Silent (SNP) | VAF 141/299 reads (47%) | catalogued as rs773541451, COSV59073914; called by muse, mutect2, varscan2
- APEX2 | c.645C>T p.C215= | Silent (SNP) | VAF 209/427 reads (49%) | catalogued as COSV100238226; called by muse, mutect2, varscan2
- BIN2 | c.426G>A p.R142= | Silent (SNP) | VAF 103/230 reads (45%) | catalogued as rs746806256; called by muse, mutect2, varscan2
- CACNA1H | c.975G>C p.P325= | Silent (SNP) | VAF 381/836 reads (46%) | catalogued as COSV61998060; called by muse, mutect2, varscan2
- CPEB2 | c.75C>T p.G25= | Silent (SNP) | VAF 57/650 reads (9%) | called by muse, mutect2
- EFCAB8 | c.1416G>A p.K472= | Silent (SNP) | VAF 196/411 reads (48%) | called by muse, mutect2, varscan2
- EFS | c.1077G>A p.R359= | Silent (SNP) | VAF 207/444 reads (47%) | catalogued as rs1169819556; called by muse, mutect2, varscan2
- FAM110B | c.531C>T p.G177= | Silent (SNP) | VAF 18/621 reads (3%) | catalogued as rs1449919905, COSV64067199; called by muse, mutect2
- IQSEC2 | c.777G>A p.A259= (on ENST00000642864 / NM_001111125.3; = p.A54= on NM_015075.2) | Silent (SNP) | VAF 255/542 reads (47%) | catalogued as rs923484172; ClinVar: likely benign; called by muse, mutect2, varscan2
- JPH2 | c.447C>T p.Y149= | Silent (SNP) | VAF 387/848 reads (46%) | catalogued as rs1481891371, COSV65903413; called by muse, mutect2, varscan2
- KIF5A | c.1698C>T p.G566= | Silent (SNP) | VAF 180/371 reads (49%) | called by muse, mutect2, varscan2
- KRTAP2-3 | c.348G>A p.P116= | Silent (SNP) | VAF 368/792 reads (46%) | called by muse, mutect2, varscan2
- NINL | c.3555G>A p.E1185= | Silent (SNP) | VAF 204/402 reads (51%) | catalogued as rs756309151; called by muse, mutect2
- PCDHA10 | c.1359G>A p.A453= | Silent (SNP) | VAF 24/828 reads (3%) | catalogued as rs372428918, COSV56494213; called by muse, mutect2
- PDE4DIP | c.6585G>A p.A2195= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs144438268; called by mutect2, varscan2
- POGZ | c.2700A>G p.L900= | Silent (SNP) | VAF 223/485 reads (46%) | catalogued as rs1005121681; called by muse, mutect2, varscan2
- PTPRO | c.2931C>T p.S977= (on ENST00000281171 / NM_030667.3; = p.S949= on NM_002848.4) | Silent (SNP) | VAF 92/214 reads (43%) | called by muse, mutect2, varscan2
- RIMS4 | c.417A>T p.G139= | Silent (SNP) | VAF 236/489 reads (48%) | called by muse, mutect2, varscan2
- RYR1 | c.4065C>T p.G1355= | Silent (SNP) | VAF 235/603 reads (39%) | catalogued as rs1293719355; called by muse, mutect2, varscan2
- SALL3 | c.417G>A p.A139= | Silent (SNP) | VAF 507/1019 reads (50%) | catalogued as rs1324041614; called by muse, mutect2, varscan2
- SEMA6B | c.204G>A p.Q68= | Silent (SNP) | VAF 201/435 reads (46%) | called by muse, mutect2, varscan2
- SEZ6L2 | c.1752C>T p.D584= (on ENST00000308713 / NM_001114099.3; = p.D514= on NM_012410.4) | Silent (SNP) | VAF 266/550 reads (48%) | called by muse, mutect2, varscan2
- SLC5A7 | c.1053C>A p.S351= | Silent (SNP) | VAF 133/288 reads (46%) | catalogued as rs1392367353; called by muse, mutect2, varscan2
- SNTG2 | c.1569C>A p.P523= | Silent (SNP) | VAF 208/501 reads (42%) | called by muse, mutect2, varscan2
- SYNE1 | c.5328C>A p.S1776= (on ENST00000367255 / NM_182961.4; = p.S1783= on NM_033071.3) | Silent (SNP) | VAF 102/281 reads (36%) | called by mutect2, varscan2
- TGM7 | c.214C>T p.L72= | Silent (SNP) | VAF 145/322 reads (45%) | catalogued as COSV71772894; called by muse, mutect2, varscan2
- TOPAZ1 | c.252G>T p.G84= | Silent (SNP) | VAF 273/601 reads (45%) | called by muse, mutect2, varscan2
- TRIM62 | c.1401G>A p.P467= | Silent (SNP) | VAF 193/444 reads (43%) | catalogued as rs772577078, COSV52222415; called by muse, mutect2, varscan2
- ZNF536 | c.1989G>A p.G663= | Silent (SNP) | VAF 334/732 reads (46%) | catalogued as COSV100834795; called by muse, varscan2
- KPNA4 | c.-278G>A | 5'UTR (SNP) | VAF 165/360 reads (46%) | catalogued as rs1017171301; called by muse, mutect2, varscan2
- MAZ | c.1280-443C>T | Intron (SNP) | VAF 393/876 reads (45%) | catalogued as rs376051318; called by muse, mutect2, varscan2
